Somatic mutation profile of tumor specimen TCGA-ED-A8O6-01A (aliquot TCGA-ED-A8O6-01A-11D-A35Z-10) from TCGA case TCGA-ED-A8O6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 50.8 years (18,572 days).
Specimen TCGA-ED-A8O6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b8b8bd4-9b99-4425-8bcc-f393b6d140c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A8O6-10A (Blood Derived Normal), aliquot TCGA-ED-A8O6-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5532f8b4-4088-4a3e-a8bf-f8d2d94ce21a

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 46, Silent 20, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.4471G>T p.E1491* | Nonsense Mutation (SNP) | VAF 112/167 reads (67%) | catalogued as COSV100653104; called by muse, mutect2, varscan2
- ANGPT1 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99862035, COSV99863128; called by muse, mutect2, varscan2
- ANKEF1 | c.2037A>C p.E679D | Missense Mutation (SNP) | VAF 141/243 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101001031; called by muse, mutect2, varscan2
- ANKMY1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs373595407; called by muse, mutect2, varscan2
- ATP12A | c.2663A>T p.Y888F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as COSV54524452, COSV99517812; called by muse, mutect2, varscan2
- BCAN | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 98/147 reads (67%) | SIFT tolerated (0.85); PolyPhen benign (0.03); catalogued as COSV100228193; called by muse, mutect2, varscan2
- BMP5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351901968, COSV100896023; called by muse, mutect2, varscan2
- C10orf90 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504282; called by muse, mutect2, varscan2
- CCDC102A | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99265107; called by muse, mutect2, varscan2
- CDC42 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100212607, COSV59661922; called by muse, mutect2, varscan2
- CFAP100 | c.1545T>G p.D515E | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.822); catalogued as COSV100729276; called by muse, mutect2, varscan2
- CFAP54 | c.5226G>T p.W1742C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100733229, COSV100733313; called by muse, mutect2, varscan2
- CHAF1A | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.236); catalogued as COSV100011270; called by muse, mutect2, varscan2
- CLCA2 | c.2131T>A p.Y711N | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100991575; called by muse, mutect2, varscan2
- CYLC1 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV100254825; called by muse, mutect2, varscan2
- DDX46 | c.2408A>G p.D803G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100844891; called by muse, mutect2, varscan2
- DDX47 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs774303230, COSV61911297; called by muse, mutect2, varscan2
- DENND2C | c.1813A>T p.K605* (on ENST00000393274 / NM_001256404.2; = p.K548* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 115/249 reads (46%) | catalogued as COSV101283941; called by muse, mutect2, varscan2
- DOCK2 | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56959774, COSV99913110; called by muse, mutect2, varscan2
- EDRF1 | c.396dup p.L133Tfs*26 | Frame Shift Ins (INS) | VAF 108/235 reads (46%) | catalogued as rs1194762434; called by mutect2, varscan2
- FN1 | c.2398A>G p.S800G | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100117322; called by muse, mutect2, varscan2
- FYCO1 | c.4038G>T p.L1346= | Splice Region (SNP) | VAF 30/54 reads (56%) | catalogued as COSV99945796; called by muse, mutect2, varscan2
- GALNT17 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.803); catalogued as rs370276097; called by muse, mutect2, varscan2
- GHDC | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780648645, COSV100054776; called by muse, mutect2, varscan2
- HAP1 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100169754; called by muse, mutect2, varscan2
- HGD | c.374T>A p.I125K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV99381086; called by muse, mutect2, varscan2
- HMCN1 | c.4369A>G p.T1457A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99630484; called by muse, mutect2, varscan2
- HMCN1 | c.16540G>C p.G5514R | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54922693, COSV99630489; called by muse, mutect2, varscan2
- HTR1E | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV59506873; called by muse, mutect2, varscan2
- LAMB3 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437223325, COSV100620390; called by muse, mutect2, varscan2
- MACF1 | c.4295A>G p.K1432R | Missense Mutation (SNP) | VAF 30/187 reads (16%) | catalogued as COSV100485006; called by muse, mutect2, varscan2
- MCF2L2 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.372); catalogued as COSV100192854; called by muse, mutect2
- MMP16 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs765641487, COSV99688820; called by muse, mutect2, varscan2
- NCOA4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs148951318; called by muse, mutect2, varscan2
- NPAS3 | c.477T>A p.D159E (on ENST00000356141 / NM_001164749.2; = p.D127E on NM_022123.3) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100388233; called by muse, mutect2, varscan2
- NTN1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99433194; called by muse, mutect2, varscan2
- PCDHGB1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as rs867459693, COSV53940130; called by muse, mutect2, varscan2
- PDS5B | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100221068; called by muse, mutect2, varscan2
- PLEC | c.10235G>A p.R3412H (on ENST00000322810 / NM_201380.4; = p.R3302H on NM_000445.5) | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs782481395, COSV59709361; called by muse, mutect2
- PRDM4 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs937067633, COSV99946630; called by muse, mutect2, varscan2
- SBF1 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100817820; called by muse, mutect2, varscan2
- SHANK1 | c.3515G>T p.S1172I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99521404; called by muse, mutect2, varscan2
- SLC44A4 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs747620646, COSV99999018; called by muse, mutect2, varscan2
- SLC4A9 | c.2765G>A p.R922Q (on ENST00000507527 / NM_001258428.2; = p.R898Q on NM_031467.3) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762998447, COSV50195995; called by muse, mutect2, varscan2
- SNIP1 | c.439T>G p.S147A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99953161; called by muse, mutect2, varscan2
- SYDE1 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100720667; called by muse, mutect2, varscan2
- TIAL1 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100958359; called by muse, mutect2, varscan2
- TRIP11 | c.2123dup p.N708Kfs*22 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | catalogued as rs747106242; called by mutect2, varscan2
- TSFM | c.548G>T p.G183V (on ENST00000323833 / NM_001172696.2; = p.G162V on NM_005726.6) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99142433; called by muse, mutect2, varscan2
- TTLL2 | c.793T>A p.F265I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99514778; called by muse, mutect2, varscan2
- UNC13A | c.2545G>T p.A849S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV99408620; called by muse, mutect2, varscan2
- USP50 | c.922A>G p.I308V (on ENST00000616326; = p.I299V on NM_203494.5) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1397126811, COSV101597726; called by muse, mutect2, varscan2
- VPS13B | c.3127T>C p.S1043P | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100662319; called by muse, mutect2
- ZNF483 | c.1712G>C p.R571T | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV100492956, COSV104396648; called by muse, mutect2, varscan2
- CLDN5 | c.302_318del p.G101Vfs*146 (on ENST00000618236 / NM_001363066.2; = p.G186Vfs*146 on NM_003277.4) | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel*, varscan2*
- NDUFB6 | c.128del p.M43Rfs*44 | Frame Shift Del (DEL) | VAF 290/903 reads (32%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.5796_5801del p.S1932_G1934delinsR | In Frame Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- UGT2B7 | c.282_283del p.K95Efs*26 | Frame Shift Del (DEL) | VAF 39/130 reads (30%) | called by mutect2, pindel, varscan2
- ANXA11 | c.684G>C p.G228= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99627204; called by muse, mutect2, varscan2
- BBS10 | c.573A>C p.S191= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99675156; called by muse, mutect2, varscan2
- C22orf42 | c.42C>G p.G14= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV101173334, COSV101173382; called by muse, mutect2, varscan2
- ERRFI1 | c.828C>T p.S276= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as rs775458241, COSV66310491; called by muse, mutect2, varscan2
- GDF15 | c.573G>A p.G191= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1244193646, COSV53250627, COSV53250716; called by muse, mutect2, varscan2
- HMCN1 | c.5493A>G p.S1831= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV99630485; called by muse, mutect2, varscan2
- HUNK | c.1434C>T p.T478= | Silent (SNP) | VAF 38/203 reads (19%) | catalogued as COSV99528591; called by muse, mutect2, varscan2
- ITPK1 | c.1188G>C p.S396= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV99968597; called by muse, mutect2, varscan2
- MAST3 | c.141G>A p.S47= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1386763932, COSV99445547; called by muse, mutect2
- MRGPRD | c.939C>T p.T313= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as rs762458441, COSV58422821; called by muse, mutect2, varscan2
- MRPL15 | c.75C>T p.A25= | Silent (SNP) | VAF 118/406 reads (29%) | catalogued as COSV99477567; called by muse, mutect2, varscan2
- NCOA2 | c.33C>T p.P11= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as rs1465537512, COSV71763466; called by muse, mutect2, varscan2
- NR2E1 | c.60C>T p.G20= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100934548; called by muse, mutect2, varscan2
- NRSN2 | c.39C>T p.R13= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs368963058; called by muse, mutect2, varscan2
- OR6C74 | c.318G>T p.G106= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100667747; called by muse, mutect2, varscan2
- OTX2 | c.174C>A p.A58= (on ENST00000408990 / NM_172337.3; = p.A66= on NM_021728.4) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100257980; called by muse, mutect2, varscan2
- RASSF4 | c.789C>T p.G263= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs751576842, COSV100437039; called by muse, mutect2, varscan2
- RTP5 | c.1398G>A p.T466= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs776573665, COSV58320190; called by muse, mutect2, varscan2
- SDSL | c.774G>C p.V258= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100615258, COSV61884837; called by muse, mutect2, varscan2
- SIX3 | c.897G>A p.T299= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV99578412; called by muse, mutect2, varscan2
